Somatic mutation profile of tumor specimen MP2PRT-PATFGX-TMP1-A (aliquot MP2PRT-PATFGX-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATFGX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (667 days).
Specimen MP2PRT-PATFGX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f77e06af-03f7-4fcd-93c3-6cd4880cb289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFGX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFGX-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d528b15-7503-43fe-aba3-0aea73c9d806

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPX | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 185/446 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs764038271, COSV56419559; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 132/374 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- GUCY2F | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 203/484 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RANBP2 | c.3127G>T p.D1043Y | Missense Mutation (SNP) | VAF 168/477 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3A3 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SLC16A10 | c.684G>C p.V228= | Silent (SNP) | VAF 11/318 reads (3%) | called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins CCCCCCCC | 5'Flank (INS) | VAF 14/62 reads (23%) | called by pindel, varscan2
- IGHV4-61 | chr14:106639118 ins CCCCCCCC | 3'Flank (INS) | VAF 24/144 reads (17%) | called by pindel, varscan2
